TCGA case TCGA-12-3652 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/159e0318-6173-440f-be07-8d956086e99d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Dead; Days to death: 1,062 days (2.9 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 60.0 years (21,920 days); Year of diagnosis: 2003; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 60 days; Treatment dose: 5,800 cGy; Number of fractions: 29; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 67 days; Number of cycles: 2; Treatment dose: 3,000 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 91 days; Days to treatment end: 133 days; Number of cycles: 1; Treatment dose: 220 mg; Prescribed dose: 110; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 161 days; Days to treatment end: 203 days; Number of cycles: 1; Treatment dose: 160 mg; Prescribed dose: 82.5; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Recurrent Disease; Days to treatment start: 228 days; Days to treatment end: 288 days; Number of cycles: 2; Treatment dose: 4,000 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Recurrent Disease; Days to treatment start: 291 days; Days to treatment end: 358 days; Number of cycles: 1; Treatment dose: 1,575 mg; Prescribed dose: 50; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Recurrent Disease; Days to treatment start: 469 days (1.3 years); Days to treatment end: 571 days (1.6 years); Number of cycles: 4; Treatment dose: 8,400 mg; Prescribed dose: 50; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Hydroxyurea; Initial disease status: Recurrent Disease; Days to treatment start: 585 days (1.6 years); Days to treatment end: 750 days (2.1 years); Treatment dose: 14,000 mg; Prescribed dose: 500; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Imatinib Mesylate; Initial disease status: Recurrent Disease; Days to treatment start: 585 days (1.6 years); Days to treatment end: 750 days (2.1 years); Treatment dose: 56,000 mg; Prescribed dose: 400; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Hydroxyurea; Initial disease status: Recurrent Disease; Days to treatment start: 750 days (2.1 years); Days to treatment end: 792 days (2.2 years); Treatment dose: 2,800 mg; Prescribed dose: 500; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Imatinib Mesylate; Initial disease status: Recurrent Disease; Days to treatment start: 750 days (2.1 years); Days to treatment end: 792 days (2.2 years); Treatment dose: 8,400 mg; Prescribed dose: 300; Prescribed dose units: mg; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 60.6 years (22,123 days); Days to diagnosis: 203 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 203 (post initial treatment): Progression or recurrence: Yes; Days to progression: 203 days.
- Days to follow up: 1,050 days (2.9 years); Disease response: With Tumor.
- Days to follow up: 1,062 days (2.9 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-3652-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-12-3652-01A-01-TS1: Section location: Top; Percent tumor cells: 88; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 12; Percent stromal cells: 0.
  Slide TCGA-12-3652-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
- Sample TCGA-12-3652-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-3652-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Pharmaceutical therapy drug name: VP 16; Therapy regimen: Recurrence.
- Drug treatment 4: Pharmaceutical therapy drug name: Hydroxurea; Therapy regimen: Recurrence.
- Drug treatment 5: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 6: Pharmaceutical therapy drug name: Gleevac; Therapy regimen: Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,062 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,062 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 203 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-3652-01A-01D-0911-01): tumor purity 0.92, ploidy 1.93, whole-genome doublings 0.
